Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A44O, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A44O-01A (Primary Tumor).

Procurement Date: Laterality: Malignant melanoma of the skin without superficial ulceration.
Breslow's depth is 5 mm.

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 0.7 x 0 x 1.2 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 5 mm.

ICD03

melanoma, NOS

872013

Site: skin, trunk

8-31-12

RO

C44.5

Reviewed (initials):	8/14/12	

Source: NCI Genomic Data Commons file 920d8062-d0c3-4d00-b429-cdb894a1d8e1 (TCGA-EB-A44O.3278362B-3B5D-4369-B9B7-CC5B33C4303B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).